Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JT, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JT-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell N65
8070/3
Site: Floor of mouth C04.9
JW 9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Floor of mouth

1 - "Lymph Nodes – Level 2a – Right":

- Four lymph nodes uninvolved by metastatic carcinoma (0/4).

2 - "Lymph Nodes – Level 3 – Right":

- Nine lymph nodes uninvolved by metastatic carcinoma (0/9).

3 - "Right pelvi-mandibulectomy specimen":

- Squamous cell carcinoma, histological grade 3, invasive, crossing the adjacent skin.

- Deep of invasion: 2.0 cm

- Tumor size: 4.5 cm

- Lymphovascular invasion: not identified.

- Perineural invasion: present.

- Submandibular salivary gland uninvolved by neoplasia.

- Submandibular lymph nodes: uninvolved by neoplasia (0/4).

- Surgical margins of skin and soft tissue uninvolved by neoplasia.

Note: Osseous tissue in decalcification process.

Addendum:

- Osseous tissue involved by neoplasia.

- Osseous margin uninvolved by neoplasia.

Source: NCI Genomic Data Commons file b1f00d60-4b96-47e4-9a27-c94200a8fcf9 (TCGA-UF-A7JT.FCAB86F4-F76A-4236-89FD-4393E5845519.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).